Somatic mutation profile of tumor specimen CDDP-ACIV-TTP1-A (aliquot CDDP-ACIV-TTP1-A-1-0-D-A572-36) from CDDP_EAGLE case CDDP-ACIV, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65 years.
Specimen CDDP-ACIV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 331e00b8-5ac4-470c-b47c-06779cbeb2ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ACIV-NB1-A (Blood Derived Normal), aliquot CDDP-ACIV-NB1-A-1-0-D-A572-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49166ec0-0d9e-423e-b255-434c9d8fcdde

The open-access MAF lists 689 somatic variants for this specimen: 491 protein-altering or splice-affecting, 112 silent, 86 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 418, Silent 112, Intron 51, Nonsense Mutation 39, Splice Site 13, 5'UTR 11, 3'UTR 10, Frame Shift Del 10, Splice Region 8, RNA 7, 5'Flank 5, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 98/555 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 17/130 reads (13%) | catalogued as rs1567556930, COSV52694020, COSV53536519; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.3317T>C p.I1106T | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.158); catalogued as rs369616854; called by muse, mutect2, varscan2
- ACSM1 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 38/398 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs751725508; called by muse, mutect2
- ADAMTS9 | c.4472G>A p.R1491K | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV55777396, COSV99898529; called by muse, mutect2, varscan2
- ADGRG4 | c.3358G>T p.V1120L | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV54949916; called by muse, mutect2, varscan2
- ADGRL3 | c.2862G>T p.L954F (on ENST00000506720 / NM_001322402.2; = p.L886F on NM_015236.6) | Missense Mutation (SNP) | VAF 37/628 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs1453878415; called by muse, mutect2
- AL592490.1 | c.2149G>A p.G717R | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as rs772345953; called by mutect2, varscan2
- ANKRD30B | c.2563C>A p.Q855K | Missense Mutation (SNP) | VAF 36/286 reads (13%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.106); catalogued as COSV57703646; called by muse, varscan2
- APOA4 | c.1167G>C p.Q389H | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV63360226; called by muse, mutect2, varscan2
- ARID2 | c.847G>T p.G283* | Nonsense Mutation (SNP) | VAF 38/203 reads (19%) | catalogued as COSV57601751; called by muse, mutect2, varscan2
- ASXL3 | c.4322C>T p.S1441L | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.054); catalogued as COSV52479136; called by muse, mutect2, varscan2
- ATG2B | c.2284C>T p.R762* | Nonsense Mutation (SNP) | VAF 34/630 reads (5%) | catalogued as COSV100737603; called by muse, mutect2
- ATP10A | c.1063G>T p.V355F | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV63523286; called by muse, mutect2
- ATP2A2 | c.1652G>C p.W551S | Missense Mutation (SNP) | VAF 38/440 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as CM990243; called by muse, mutect2
- ATP2A2 | c.1653G>T p.W551C | Missense Mutation (SNP) | VAF 38/440 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV58044941; called by muse, mutect2
- BAZ2B | c.3723G>C p.L1241F | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV99681113; called by muse, mutect2
- BCL11A | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59637068; called by muse, mutect2, varscan2
- BRINP3 | c.2036C>A p.A679E | Missense Mutation (SNP) | VAF 28/301 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1486612699; called by muse, mutect2
- BSDC1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs1432028949; called by muse, mutect2
- C5AR1 | c.656C>A p.T219K | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV61892087; called by muse, mutect2, varscan2
- CAVIN1 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 22/301 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100824621, COSV63811803; called by muse, mutect2
- CDH12 | c.810del p.S272Afs*5 | Frame Shift Del (DEL) | VAF 18/140 reads (13%) | catalogued as COSV101201497, COSV66438116; called by mutect2, pindel
- CDH18 | c.1803T>A p.H601Q | Missense Mutation (SNP) | VAF 49/368 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV56931555; called by muse, mutect2, varscan2
- CDH2 | c.1691C>A p.P564Q | Missense Mutation (SNP) | VAF 49/451 reads (11%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.823); catalogued as COSV52299737; called by muse, mutect2, varscan2
- CELSR2 | c.7235G>T p.R2412L | Missense Mutation (SNP) | VAF 44/452 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as rs1409978941, COSV54766144; called by muse, mutect2
- CENPF | c.3362C>G p.S1121C | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV100871701; called by muse, mutect2
- CEP250 | c.3940G>T p.E1314* | Nonsense Mutation (SNP) | VAF 25/252 reads (10%) | catalogued as COSV61168779; called by muse, mutect2
- CFAP47 | c.1975C>T p.R659C | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs759375823; called by muse, mutect2
- CHST9 | c.140G>C p.R47T | Missense Mutation (SNP) | VAF 26/488 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as rs1398726259, COSV99410318; called by muse, mutect2
- CNGB3 | c.212-1G>A p.X71_splice | Splice Site (SNP) | VAF 84/396 reads (21%) | catalogued as COSV60702757; called by mutect2, varscan2
- COL4A5 | c.3710del p.P1237Qfs*62 | Frame Shift Del (DEL) | VAF 16/76 reads (21%) | catalogued as CX107380, COSV60360509; called by mutect2, pindel, varscan2
- CPED1 | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.134); catalogued as rs1263909106; called by muse, mutect2, varscan2
- CR1L | c.1605C>A p.S535R | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV54325723, COSV54329447; called by muse, mutect2
- CRISPLD1 | c.131del p.G44Vfs*5 | Frame Shift Del (DEL) | VAF 60/682 reads (9%) | catalogued as COSV51545666, COSV51546514; called by mutect2, pindel
- CTTN | c.1528G>T p.E510* | Nonsense Mutation (SNP) | VAF 40/432 reads (9%) | catalogued as COSV57233155, COSV57236218; called by muse, mutect2
- CUL7 | c.3229G>A p.E1077K | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV54819562; called by muse, mutect2
- DCX | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV57568438, COSV57576414; called by muse, mutect2, varscan2
- DHRS2 | c.701A>G p.K234R | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1340395565; called by muse, mutect2, varscan2
- DLX2 | c.328C>A p.L110M | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.688); catalogued as rs1296777988; called by muse, mutect2
- DMXL2 | c.2146C>A p.H716N | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as COSV51841111, COSV51849412; called by muse, mutect2, varscan2
- DNAH9 | c.11192T>C p.I3731T | Missense Mutation (SNP) | VAF 67/325 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.05); catalogued as rs943733730; called by muse, mutect2, varscan2
- EN1 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); catalogued as rs1443690023; called by muse, mutect2
- ENPP2 | c.2354G>A p.C785Y (on ENST00000075322 / NM_001040092.3; = p.C837Y on NM_006209.5) | Missense Mutation (SNP) | VAF 33/540 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50017585; called by muse, mutect2
- F12 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 23/462 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99499857; called by muse, mutect2
- FAM110B | c.126G>T p.E42D | Missense Mutation (SNP) | VAF 29/266 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as COSV64068846; called by muse, mutect2, varscan2
- FAM110B | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100826126, COSV64068214; called by muse, mutect2
- FAM81A | c.297A>G p.V99= | Splice Region (SNP) | VAF 13/176 reads (7%) | catalogued as rs1176014230; called by muse, mutect2
- FAM90A10P | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 49/508 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs778902406; called by muse, mutect2, varscan2
- FANCM | c.3753T>A p.D1251E | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV57502314; called by muse, mutect2, varscan2
- FAT3 | c.11742C>A p.D3914E | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53118440; called by muse, mutect2
- FHL2 | c.326T>C p.M109T | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.629); catalogued as COSV100362871; called by muse, mutect2
- FMN2 | c.4865T>G p.I1622S | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as COSV60414894; called by muse, mutect2
- FPGT-TNNI3K | c.71C>A p.S24* | Nonsense Mutation (SNP) | VAF 17/212 reads (8%) | catalogued as COSV63047521; called by muse, mutect2
- FREM1 | c.854A>G p.Y285C | Missense Mutation (SNP) | VAF 57/334 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.525); catalogued as rs763347337; called by muse, mutect2, varscan2
- FRMPD4 | c.1833C>A p.S611R | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.042); catalogued as rs776472956; called by muse, mutect2, varscan2
- GMFG | c.283+1G>A p.X95_splice | Splice Site (SNP) | VAF 34/236 reads (14%) | catalogued as COSV53419569; called by muse, mutect2, varscan2
- GOLGA3 | c.4162G>A p.E1388K | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.904); catalogued as rs145054007; called by muse, mutect2
- GRIK3 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 35/306 reads (11%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.018); catalogued as COSV100902267; called by muse, mutect2, varscan2
- GUCY1A2 | c.1822G>T p.G608* | Nonsense Mutation (SNP) | VAF 13/143 reads (9%) | catalogued as COSV56507617; called by muse, mutect2
- HCN1 | c.2113A>T p.S705C | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); catalogued as COSV100297780; called by muse, mutect2, varscan2
- HEATR5B | c.3805C>T p.H1269Y | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1359600541; called by muse, mutect2, varscan2
- HECTD4 | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 34/512 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs1327746842; called by muse, mutect2
- HECW2 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 21/390 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); catalogued as COSV53654179, COSV99647954; called by muse, mutect2
- HEPH | c.2128A>G p.R710G (on ENST00000343002; = p.R443G on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100295821; called by muse, mutect2
- HORMAD1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59270361; called by muse, varscan2
- HRH1 | c.323A>G p.Y108C | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1376009394; called by muse, mutect2, varscan2
- IAPP | c.80G>A p.S27N | Missense Mutation (SNP) | VAF 88/512 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as rs1286099292, COSV53714316; called by muse, mutect2, varscan2
- IGHV4-61 | c.171G>C p.W57C | Missense Mutation (SNP) | VAF 30/347 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1199622314; called by muse, mutect2
- IGLL1 | c.286C>G p.H96D | Missense Mutation (SNP) | VAF 54/496 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV50770206; called by muse, mutect2, varscan2
- INTS8 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 32/531 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV58248985; called by muse, mutect2
- ITIH2 | c.271C>A p.Q91K | Missense Mutation (SNP) | VAF 70/510 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.114); catalogued as COSV100623227; called by muse, mutect2, varscan2
- ITLN2 | c.484T>C p.W162R | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs201653416; called by mutect2, varscan2
- KASH5 | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV71358624; called by muse, mutect2
- KCNJ4 | c.821T>C p.M274T | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV100341381; called by muse, mutect2, varscan2
- KRT33A | c.552G>T p.K184N | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as rs1231400954, COSV50365760; called by muse, mutect2
- KRTAP13-3 | c.308G>C p.G103A | Missense Mutation (SNP) | VAF 72/398 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV61878978; called by muse, mutect2, varscan2
- LCE1A | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 58/378 reads (15%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.844); catalogued as COSV58727895; called by muse, mutect2, varscan2
- LGI2 | c.1557C>G p.D519E | Missense Mutation (SNP) | VAF 44/209 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.963); catalogued as COSV66124382; called by muse, mutect2, varscan2
- LRP5 | c.1507G>T p.G503W | Missense Mutation (SNP) | VAF 58/299 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53713412; called by muse, mutect2, varscan2
- MAGEB6 | c.302C>A p.S101Y | Missense Mutation (SNP) | VAF 61/205 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs200942471; called by muse, mutect2, varscan2
- MAPK10 | c.325G>T p.E109* (on ENST00000359221 / NM_001351625.2; = p.E147* on NM_002753.5) | Nonsense Mutation (SNP) | VAF 20/153 reads (13%) | catalogued as COSV60380534; called by muse, mutect2, varscan2
- MASP1 | c.383T>C p.F128S | Missense Mutation (SNP) | VAF 81/492 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV51458049; called by muse, varscan2
- MED30 | c.145A>G p.M49V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as rs1285475742; called by muse, mutect2, varscan2
- MED30 | c.419G>C p.R140P | Missense Mutation (SNP) | VAF 61/383 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV52068209; called by muse, mutect2, varscan2
- MFAP4 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs17855749; called by mutect2, varscan2
- MGAM2 | c.3353A>G p.Y1118C | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV101522936; called by muse, mutect2
- MPDZ | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 16/281 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.383); catalogued as rs1039177904, COSV59949730; called by muse, mutect2
- MRPS28 | c.79C>G p.R27G | Missense Mutation (SNP) | VAF 34/345 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs1391525747, COSV52562069, COSV52563206; called by muse, mutect2, varscan2
- MUC16 | c.33775G>A p.E11259K | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.022); catalogued as rs1324584641; called by muse, mutect2, varscan2
- MYH4 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV55116827; called by muse, mutect2, varscan2
- MYH8 | c.3148G>T p.D1050Y | Missense Mutation (SNP) | VAF 29/279 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101238342; called by muse, mutect2, varscan2
- MYO3A | c.3023C>A p.S1008* | Nonsense Mutation (SNP) | VAF 84/854 reads (10%) | catalogued as COSV56328707; called by muse, mutect2
- MYOM1 | c.3964G>C p.D1322H | Missense Mutation (SNP) | VAF 24/383 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55296743; called by muse, mutect2
- NAA15 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.32); catalogued as rs1418072372; called by muse, mutect2, varscan2
- NAV3 | c.6722G>T p.R2241L (on ENST00000397909 / NM_001024383.2; = p.R2219L on NM_014903.6) | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV57115621; called by muse, mutect2, varscan2
- NCKAP5 | c.593C>A p.A198E | Missense Mutation (SNP) | VAF 45/396 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV58474206; called by muse, mutect2, varscan2
- NCR1 | c.417G>T p.K139N | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767656063; called by muse, mutect2, varscan2
- NEK10 | c.2384C>G p.S795C | Missense Mutation (SNP) | VAF 110/669 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.109); catalogued as COSV55362356; called by muse, mutect2, varscan2
- NEURL1B | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as rs1416869337; called by muse, mutect2
- NFIC | c.1114G>T p.A372S | Missense Mutation (SNP) | VAF 43/319 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs570186658; called by muse, mutect2, varscan2
- NKD1 | c.213G>C p.L71F | Missense Mutation (SNP) | VAF 28/344 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV51689381; called by muse, mutect2
- NLRP7 | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 23/346 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.201); catalogued as rs758296123, COSV60177190; called by muse, mutect2
- NMUR2 | c.482G>T p.R161L | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.107); catalogued as COSV54920398, COSV54921346; called by muse, mutect2, varscan2
- NOS2 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 22/441 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100569481; called by muse, mutect2
- NOTUM | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 17/254 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as rs1032662187, COSV68826921; called by muse, mutect2
- NRCAM | c.1522G>A p.G508R (on ENST00000379028 / NM_001371124.1; = p.G502R on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61051455; called by muse, mutect2, varscan2
- OLFM4 | c.186C>G p.S62R | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV99524198; called by muse, mutect2, varscan2
- OR2B6 | c.631C>A p.L211M | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as rs367648654, COSV55128722; called by muse, mutect2
- OR2L13 | c.727C>A p.H243N | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63547572; called by muse, mutect2, varscan2
- OR2T3 | c.607C>T p.L203F | Missense Mutation (SNP) | VAF 34/337 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.03); catalogued as rs754901360, COSV100612989; called by muse, mutect2
- OR3A2 | c.492C>A p.N164K | Missense Mutation (SNP) | VAF 92/499 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV68694960, COSV68695094; called by muse, mutect2, varscan2
- OR52A5 | c.242C>G p.P81R | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1226425619; called by muse, mutect2, varscan2
- OR5D16 | c.745G>T p.A249S | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV101004148; called by muse, mutect2, varscan2
- OR5J2 | c.442T>A p.S148T | Missense Mutation (SNP) | VAF 22/400 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.867); catalogued as COSV100399119; called by muse, mutect2
- OR6Y1 | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 42/480 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753757437, COSV56929773; called by muse, mutect2
- OR7E24 | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 50/619 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV71702271; called by muse, mutect2
- OR8B2 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 28/459 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV66664644, COSV66665433; called by muse, mutect2
- PABPC5 | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 53/272 reads (19%) | catalogued as COSV57042092; called by muse, mutect2, varscan2
- PCLO | c.5282G>T p.R1761I | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61659967; called by mutect2, varscan2
- PKHD1L1 | c.3826T>C p.Y1276H | Missense Mutation (SNP) | VAF 39/424 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs1187691353; called by muse, mutect2
- PLCE1 | c.71C>A p.S24* | Nonsense Mutation (SNP) | VAF 62/382 reads (16%) | catalogued as COSV53374110; called by muse, mutect2, varscan2
- PLPP7 | c.672C>A p.C224* | Nonsense Mutation (SNP) | VAF 30/241 reads (12%) | catalogued as COSV64841385; called by muse, mutect2, varscan2
- POTEH | c.469T>A p.W157R | Missense Mutation (SNP) | VAF 84/931 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV58885543; called by muse, varscan2
- PPP4R1 | c.2477A>G p.N826S (on ENST00000400556 / NM_001042388.3; = p.N809S on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/465 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs759424700; called by muse, mutect2, varscan2
- PRR23C | c.721C>A p.P241T | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as rs749283724; called by mutect2, varscan2
- PTPRD | c.5482C>G p.H1828D | Missense Mutation (SNP) | VAF 46/278 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61971205; called by muse, mutect2, varscan2
- PTPRD | c.2854A>C p.T952P | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV61925703; called by muse, mutect2, varscan2
- RELN | c.7096G>C p.V2366L | Missense Mutation (SNP) | VAF 104/726 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.418); catalogued as COSV59027063; called by muse, mutect2, varscan2
- RIMS2 | c.2635C>A p.P879T (on ENST00000666250 / NM_001348490.2; = p.P687T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.395); catalogued as COSV51710761; called by muse, mutect2, varscan2
- RNF180 | c.1318T>G p.F440V | Missense Mutation (SNP) | VAF 48/479 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66632956; called by muse, mutect2
- RPUSD2 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs781484718, COSV100225315; called by mutect2, varscan2
- RYR2 | c.3934G>A p.E1312K | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV63675798; called by muse, mutect2, varscan2
- SALL1 | c.3701G>A p.W1234* | Nonsense Mutation (SNP) | VAF 44/554 reads (8%) | catalogued as COSV51755122; called by muse, mutect2
- SCG3 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.05); catalogued as COSV99590838; called by muse, mutect2
- SCN4A | c.3796G>A p.E1266K | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1398605254, COSV101438278; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN8A | c.1492A>T p.R498W | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV61991760; called by muse, mutect2
- SEMA3E | c.2306C>A p.P769H | Missense Mutation (SNP) | VAF 30/412 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57088198; called by muse, mutect2
- SETBP1 | c.1621A>G p.T541A | Missense Mutation (SNP) | VAF 18/243 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1568234864; called by muse, mutect2
- SFXN1 | c.960G>T p.K320N | Missense Mutation (SNP) | VAF 19/302 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58495462; called by muse, mutect2
- SHOX2 | c.631G>A p.A211T (on ENST00000441443 / NM_006884.3; = p.A235T on NM_003030.4) | Missense Mutation (SNP) | VAF 49/270 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.461); catalogued as rs200467564; called by muse, mutect2, varscan2
- SI | c.606A>C p.Q202H | Missense Mutation (SNP) | VAF 27/367 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV52267958; called by muse, mutect2
- SLC16A1 | c.1285G>A p.V429I | Missense Mutation (SNP) | VAF 42/404 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs151166713; called by muse, mutect2, varscan2
- SLC7A13 | c.680T>C p.I227T | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs532897792; called by muse, varscan2
- SLFN5 | c.2030G>T p.G677V | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs971588055; called by muse, mutect2, varscan2
- SOX11 | c.773C>A p.P258Q | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.012); catalogued as rs868349180, COSV58988152; called by muse, varscan2
- SP9 | c.606C>A p.S202R | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV67601890; called by muse, mutect2, varscan2
- SPEG | c.9710G>A p.R3237Q | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs563295911; called by muse, mutect2, varscan2
- SPRY2 | c.76G>T p.G26W | Missense Mutation (SNP) | VAF 86/758 reads (11%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.964); catalogued as COSV65701544; called by muse, mutect2, varscan2
- SPTBN1 | c.6476C>T p.T2159M | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.112); catalogued as rs35357181; called by muse, mutect2, varscan2
- TACR3 | c.1187G>T p.R396L | Missense Mutation (SNP) | VAF 61/604 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.753); catalogued as COSV100510776; called by muse, mutect2
- TACR3 | c.913G>T p.V305F | Missense Mutation (SNP) | VAF 50/391 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1208774798; called by muse, mutect2, varscan2
- TEKT4 | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV99726133; called by mutect2, varscan2
- THEMIS | c.1516G>T p.V506L | Missense Mutation (SNP) | VAF 36/302 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV64072662; called by muse, mutect2, varscan2
- THEMIS | c.858A>C p.E286D | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs768285653; called by muse, mutect2
- TMEM132D | c.947C>A p.T316N | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.463); catalogued as COSV70625056; called by muse, mutect2, varscan2
- TMPRSS15 | c.2581G>A p.E861K | Missense Mutation (SNP) | VAF 62/418 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV99517357; called by muse, varscan2
- TRA2A | c.640C>G p.H214D | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.379); catalogued as COSV51716646; called by muse, mutect2
- TTC33 | c.44C>A p.S15* | Nonsense Mutation (SNP) | VAF 55/405 reads (14%) | catalogued as COSV100531851, COSV100532132; called by muse, mutect2, varscan2
- TTN | c.44152G>C p.D14718H (on ENST00000591111; = p.D7294H on NM_003319.4) | Missense Mutation (SNP) | VAF 24/239 reads (10%) | PolyPhen probably damaging (0.999); catalogued as COSV60310062; called by muse, mutect2, varscan2
- TTN | c.34694del p.P11565Qfs*6 (on ENST00000591111; = p.P10638Qfs*6 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 50/425 reads (12%) | catalogued as COSV60196071; called by mutect2, pindel, varscan2
- TTN | c.34244C>A p.P11415H (on ENST00000591111; = p.P10488H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/141 reads (14%) | PolyPhen benign (0.24); catalogued as rs767601091; called by muse, mutect2, varscan2
- TTN | c.6007C>A p.R2003S (on ENST00000591111; = p.R1957S on NM_003319.4) | Missense Mutation (SNP) | VAF 18/153 reads (12%) | PolyPhen probably damaging (0.998); catalogued as COSV59900446; called by muse, mutect2
- UNC79 | c.2894A>C p.K965T (on ENST00000393151 / NM_001346218.2; = p.K788T on NM_020818.5) | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as COSV56371798, COSV56383251; called by muse, mutect2, varscan2
- UNC80 | c.5422C>A p.R1808S | Missense Mutation (SNP) | VAF 24/360 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99779625; called by muse, mutect2
- VENTX | c.596C>A p.P199H | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV100384034; called by muse, mutect2, varscan2
- WDFY3 | c.4880C>T p.S1627L | Missense Mutation (SNP) | VAF 18/331 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1243554564, COSV99883953; called by muse, mutect2
- WIPF1 | c.646G>T p.G216W | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV55812891, COSV55816754; called by mutect2, varscan2
- XIRP2 | c.815G>A p.G272E (on ENST00000628543; = p.G447E on NM_152381.6) | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.061); catalogued as COSV54725511; called by muse, mutect2
- ZFHX4 | c.2458C>A p.L820I | Missense Mutation (SNP) | VAF 18/257 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV51472664; called by muse, mutect2
- ZFPM2 | c.2050C>A p.P684T | Missense Mutation (SNP) | VAF 62/866 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65874770; called by muse, mutect2
- ZIM3 | c.901C>G p.H301D | Missense Mutation (SNP) | VAF 19/264 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1478997718; called by muse, mutect2
- ZNF382 | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as COSV53088091; called by muse, mutect2, varscan2
- ZNF565 | c.277G>C p.D93H (on ENST00000355114; = p.D53H on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as rs375713820; called by muse, mutect2, varscan2
- ZNF670 | c.480G>T p.M160I | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV63607693; called by muse, mutect2, varscan2
- ZNF676 | c.592G>T p.E198* (on ENST00000650058; = p.E166* on NM_001001411.3) | Nonsense Mutation (SNP) | VAF 33/210 reads (16%) | catalogued as COSV68092153; called by muse, mutect2, varscan2
- ZW10 | c.1324G>T p.D442Y | Missense Mutation (SNP) | VAF 43/304 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as rs200000547; called by muse, mutect2, varscan2
- ABCA13 | c.3668A>C p.H1223P | Missense Mutation (SNP) | VAF 73/573 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- ABCA13 | c.5973G>C p.E1991D | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ABCA5 | c.2234T>G p.V745G | Missense Mutation (SNP) | VAF 42/263 reads (16%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- ADAM12 | c.2182T>C p.Y728H | Missense Mutation (SNP) | VAF 28/635 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); called by muse, mutect2
- ADAMTS12 | c.3767A>C p.Q1256P | Missense Mutation (SNP) | VAF 94/457 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ADAMTS19 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- ADAMTS20 | c.3580C>A p.H1194N | Missense Mutation (SNP) | VAF 39/280 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- ADAR | c.3202+4A>T | Splice Region (SNP) | VAF 32/321 reads (10%) | called by muse, mutect2, varscan2
- ADGB | c.3052A>G p.I1018V | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.146); called by muse, mutect2
- ADGB | c.3759G>T p.K1253N | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2
- AFG3L2 | c.1501G>C p.E501Q | Missense Mutation (SNP) | VAF 51/820 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.053); called by muse, mutect2
- AKAP4 | c.948G>C p.Q316H | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- AMER3 | c.1791G>C p.R597S | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- AMOTL1 | c.1621G>T p.A541S | Missense Mutation (SNP) | VAF 68/294 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AMZ2 | c.566del p.G189Dfs*5 | Frame Shift Del (DEL) | VAF 37/164 reads (23%) | called by mutect2, pindel, varscan2
- ANK2 | c.1667A>T p.H556L | Missense Mutation (SNP) | VAF 42/447 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.316); called by muse, mutect2
- ANK2 | c.9338G>C p.R3113P | Missense Mutation (SNP) | VAF 54/582 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANTXR1 | c.95G>A p.R32K | Missense Mutation (SNP) | VAF 63/477 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATG4A | c.374G>T p.C125F | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- BCL11B | c.1150C>T p.R384C (on ENST00000357195 / NM_001282237.2; = p.R313C on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BIRC6 | c.1618del p.A540Qfs*5 | Frame Shift Del (DEL) | VAF 46/360 reads (13%) | called by mutect2, pindel, varscan2
- BIRC6 | c.6820G>A p.E2274K | Missense Mutation (SNP) | VAF 19/272 reads (7%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); called by muse, mutect2
- BLVRA | c.627G>C p.K209N | Missense Mutation (SNP) | VAF 38/386 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- BTN2A1 | c.1430G>T p.R477L | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.053); called by mutect2, varscan2
- C16orf78 | c.368A>T p.Y123F | Missense Mutation (SNP) | VAF 61/463 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- C1orf141 | c.1031C>G p.T344S | Missense Mutation (SNP) | VAF 69/481 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- C1orf141 | c.938C>A p.T313K | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- C1orf87 | c.1609G>T p.E537* | Nonsense Mutation (SNP) | VAF 30/265 reads (11%) | called by muse, mutect2, varscan2
- CACNA1E | c.4612T>G p.F1538V | Missense Mutation (SNP) | VAF 28/409 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- CACNA1H | c.4395G>C p.R1465S | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.262); called by muse, mutect2
- CASP2 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 32/747 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.333); called by muse, mutect2
- CCDC168 | c.6988A>T p.T2330S | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CCDC178 | c.1793G>C p.R598T | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- CCDC197 | c.716G>A p.R239K | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.892); called by muse, mutect2
- CCDC88C | c.3832del p.H1278Tfs*5 | Frame Shift Del (DEL) | VAF 38/270 reads (14%) | called by mutect2, pindel, varscan2
- CDC123 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- CDC14C | c.851A>G p.H284R (on ENST00000428251; = p.H177R on NM_152627.3) | Missense Mutation (SNP) | VAF 46/356 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CDC73 | c.1036C>G p.Q346E | Missense Mutation (SNP) | VAF 34/452 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.029); called by muse, mutect2
- CDH12 | c.1855G>A p.A619T | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CDH2 | c.904G>C p.G302R | Missense Mutation (SNP) | VAF 112/399 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDH20 | c.1269C>A p.I423= | Splice Region (SNP) | VAF 16/106 reads (15%) | called by muse, varscan2
- CDH6 | c.973C>G p.Q325E | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- CDH8 | c.1823G>T p.C608F | Missense Mutation (SNP) | VAF 62/678 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CDH8 | c.1087G>C p.D363H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by mutect2, varscan2
- CDS2 | c.982-1G>C p.X328_splice | Splice Site (SNP) | VAF 28/291 reads (10%) | called by muse, mutect2
- CENPC | c.2734A>C p.T912P | Missense Mutation (SNP) | VAF 42/331 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- CHORDC1 | c.440A>T p.D147V | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CIT | c.3088G>C p.E1030Q | Missense Mutation (SNP) | VAF 25/702 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- CLINT1 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 21/364 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- CLRN2 | c.200G>C p.R67P | Missense Mutation (SNP) | VAF 64/279 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- CLRN3 | c.565C>T p.L189F | Missense Mutation (SNP) | VAF 117/537 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLTB | c.436C>A p.Q146K | Missense Mutation (SNP) | VAF 48/376 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- COL12A1 | c.1295C>G p.S432* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- COL1A2 | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 31/371 reads (8%) | called by muse, mutect2
- COL4A1 | c.3733G>T p.G1245C | Missense Mutation (SNP) | VAF 60/293 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A2 | c.3226G>T p.A1076S | Missense Mutation (SNP) | VAF 66/403 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CSMD3 | c.7430G>T p.S2477I (on ENST00000297405 / NM_001363185.1; = p.S2373I on NM_052900.3) | Missense Mutation (SNP) | VAF 120/738 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CSMD3 | c.5995G>A p.G1999R (on ENST00000297405 / NM_001363185.1; = p.G1895R on NM_052900.3) | Missense Mutation (SNP) | VAF 102/535 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- CSPP1 | c.1605-1G>T p.X535_splice (on ENST00000676605; = p.X494_splice on NM_024790.6) | Splice Site (SNP) | VAF 16/237 reads (7%) | called by muse, mutect2
- CTAGE4 | c.692C>A p.A231D | Missense Mutation (SNP) | VAF 68/650 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CTHRC1 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 51/281 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- CUX1 | c.4168G>C p.D1390H | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.066); called by muse, mutect2
- CYP11B2 | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 67/420 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CYP7B1 | c.1044C>A p.S348R | Missense Mutation (SNP) | VAF 50/609 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.703); called by muse, mutect2
- DAB1 | c.663+2T>A p.X221_splice | Splice Site (SNP) | VAF 45/317 reads (14%) | called by muse, mutect2, varscan2
- DACH1 | c.1012A>T p.I338F | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- DCHS2 | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- DGKB | c.93T>G p.D31E | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); called by muse, mutect2
- DIO2 | c.725del p.G242Efs*? | Frame Shift Del (DEL) | VAF 60/364 reads (16%) | called by mutect2, pindel, varscan2
- DNAH17 | c.4439C>T p.S1480F | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2
- DNAH5 | c.10690A>T p.S3564C | Missense Mutation (SNP) | VAF 121/553 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- DNAI1 | c.48G>T p.Q16H | Missense Mutation (SNP) | VAF 53/505 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- DRD1 | c.1141A>G p.I381V | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DRD2 | c.965C>A p.P322H | Missense Mutation (SNP) | VAF 85/449 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- DSCAML1 | c.1082G>T p.G361V (on ENST00000321322; = p.G301V on NM_020693.4) | Missense Mutation (SNP) | VAF 14/271 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- DSPP | c.41G>C p.W14S | Missense Mutation (SNP) | VAF 36/836 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- EBF3 | c.1649del p.P550Lfs*8 | Frame Shift Del (DEL) | VAF 83/387 reads (21%) | called by mutect2, pindel, varscan2
- EFCAB3 | c.724A>G p.I242V | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- EFR3A | c.778C>T p.H260Y | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- EHBP1L1 | c.3764G>T p.R1255L | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EIF4G1 | c.3780+4G>T | Splice Region (SNP) | VAF 34/222 reads (15%) | called by muse, mutect2, varscan2
- ELAPOR2 | c.1573T>C p.C525R (on ENST00000450689 / NM_001142749.3; = p.C358R on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELFN1 | c.2387C>A p.A796E | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- EMILIN3 | c.1055A>T p.H352L | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.366); called by muse, mutect2
- EPHA3 | c.1569G>T p.K523N | Missense Mutation (SNP) | VAF 13/211 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.058); called by muse, mutect2
- ERBB4 | c.3359A>T p.Q1120L | Missense Mutation (SNP) | VAF 36/450 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2
- EZHIP | c.303G>T p.Q101H | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- EZHIP | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- F13B | c.541G>T p.A181S | Missense Mutation (SNP) | VAF 30/542 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.026); called by muse, mutect2
- FAM186B | c.2075C>G p.A692G | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- FAR2 | c.423G>T p.Q141H | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- FASTKD5 | c.1371G>T p.E457D | Missense Mutation (SNP) | VAF 16/251 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.777); called by muse, mutect2
- FASTKD5 | c.455G>C p.R152T | Missense Mutation (SNP) | VAF 11/224 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FBH1 | c.2162G>A p.R721K (on ENST00000362091 / NM_178150.3; = p.R772K on NM_032807.4) | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- FERMT1 | c.1359G>C p.L453F | Missense Mutation (SNP) | VAF 67/496 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- FHOD3 | c.22G>T p.V8L | Missense Mutation (SNP) | VAF 39/283 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- FNDC4 | c.350A>T p.Q117L | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- FNDC7 | c.1879+1G>T p.X627_splice | Splice Site (SNP) | VAF 12/42 reads (29%) | called by muse, varscan2
- FREM2 | c.7213A>G p.T2405A | Missense Mutation (SNP) | VAF 40/394 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2
- FREM3 | c.5895G>T p.Q1965H | Missense Mutation (SNP) | VAF 62/768 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2
- FREM3 | c.1867T>A p.S623T | Missense Mutation (SNP) | VAF 55/289 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- GAA | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 42/311 reads (14%) | called by muse, mutect2, varscan2
- GABRA2 | c.970G>T p.V324L | Missense Mutation (SNP) | VAF 48/764 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- GABRG1 | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 67/394 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- GFUS | c.950A>T p.E317V | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- GIMAP1 | c.761G>C p.R254T | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- GIMAP5 | c.810G>T p.K270N | Missense Mutation (SNP) | VAF 42/398 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- GIMAP5 | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 41/392 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- GON4L | c.-26-3C>T | Splice Region (SNP) | VAF 17/182 reads (9%) | called by muse, mutect2
- GPR65 | c.824C>A p.T275K | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GRHL2 | c.1122G>C p.L374F | Missense Mutation (SNP) | VAF 46/616 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- GRID1 | c.1158C>G p.D386E | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- GRM1 | c.631C>A p.Q211K | Missense Mutation (SNP) | VAF 38/470 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, mutect2
- GSDME | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 50/650 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.156); called by muse, mutect2
- HELQ | c.1871G>A p.G624D | Missense Mutation (SNP) | VAF 46/528 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.017); called by muse, mutect2
- HELZ | c.481+1G>T p.X161_splice | Splice Site (SNP) | VAF 30/278 reads (11%) | called by muse, mutect2
- HGF | c.340C>A p.H114N | Missense Mutation (SNP) | VAF 26/378 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.013); called by muse, mutect2
- HINFP | c.652A>T p.I218F | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- HMGCS1 | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 18/360 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.17); called by muse, mutect2
- HOXA13 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 76/935 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.298); called by muse, mutect2
- HRNR | c.919C>G p.P307A | Missense Mutation (SNP) | VAF 48/421 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HSPA6 | c.1538G>A p.S513N | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.352); called by muse, mutect2
- IGHD | c.1114C>A p.L372I | Missense Mutation (SNP) | VAF 40/267 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- IL22RA2 | c.59C>A p.A20E | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0.193); called by mutect2, varscan2
- ING5 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 54/353 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IQSEC1 | c.1031G>T p.W344L | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); called by muse, varscan2
- IQSEC2 | c.1718G>A p.R573H (on ENST00000642864 / NM_001111125.3; = p.R368H on NM_015075.2) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ITPRID1 | c.17C>G p.S6* | Nonsense Mutation (SNP) | VAF 37/230 reads (16%) | called by muse, mutect2, varscan2
- ITPRID1 | c.672C>G p.I224M | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); called by muse, mutect2
- KCNJ13 | c.514T>A p.F172I | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNK10 | c.1181C>A p.P394H | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KDM4A | c.2368G>T p.D790Y | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- KDM5B | c.278T>A p.L93* | Nonsense Mutation (SNP) | VAF 20/208 reads (10%) | called by muse, mutect2, varscan2
- KIAA1210 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, varscan2
- KIF26B | c.1849G>T p.G617C | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- KIF26B | c.1850G>T p.G617V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- KLRC2 | c.635A>T p.N212I | Missense Mutation (SNP) | VAF 78/495 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KMT2D | c.5138G>A p.G1713E | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.056); called by muse, mutect2
- KRTAP11-1 | c.356G>T p.S119I | Missense Mutation (SNP) | VAF 62/363 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- KRTAP9-7 | c.207C>A p.S69R | Missense Mutation (SNP) | VAF 23/236 reads (10%) | SIFT deleterious (0.02); called by muse, mutect2, varscan2
- L3MBTL3 | c.121G>T p.G41* | Nonsense Mutation (SNP) | VAF 21/232 reads (9%) | called by muse, mutect2
- LAMA4 | c.3862A>T p.N1288Y (on ENST00000230538 / NM_001105206.3; = p.N1281Y on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/576 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2
- LHX3 | c.84C>G p.I28M (on ENST00000371748 / NM_178138.6; = p.I33M on NM_014564.5) | Missense Mutation (SNP) | VAF 32/368 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- LRP5 | c.380C>G p.S127* | Nonsense Mutation (SNP) | VAF 26/370 reads (7%) | called by muse, mutect2
- LRRC4B | c.616C>G p.L206V | Missense Mutation (SNP) | VAF 48/427 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LTBP4 | c.1243G>A p.D415N (on ENST00000308370 / NM_001042544.1; = p.D378N on NM_003573.2) | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.037); called by muse, mutect2
- MACF1 | c.8893G>C p.E2965Q | Missense Mutation (SNP) | VAF 18/365 reads (5%) | called by muse, mutect2
- MADD | c.4692A>T p.E1564D | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- MBD4 | c.1670A>T p.H557L | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MC5R | c.424G>T p.V142F | Missense Mutation (SNP) | VAF 109/359 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- METTL17 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.232); called by muse, mutect2
- METTL22 | c.1180-2A>T p.X394_splice | Splice Site (SNP) | VAF 48/221 reads (22%) | called by muse, mutect2, varscan2
- MGAM2 | c.4923G>C p.T1641= | Splice Region (SNP) | VAF 30/236 reads (13%) | called by muse, mutect2, varscan2
- MKX | c.983C>A p.T328N | Missense Mutation (SNP) | VAF 22/414 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.283); called by muse, mutect2
- MLIP | c.116C>G p.T39S | Missense Mutation (SNP) | VAF 65/803 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2
- MLYCD | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.146); called by muse, mutect2
- MMP2 | c.1593_1595del p.K531_A532delinsN | In Frame Del (DEL) | VAF 73/584 reads (13%) | called by mutect2, pindel, varscan2
- MON1B | c.1219G>C p.A407P | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- MPO | c.947G>T p.C316F | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- MS4A3 | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 53/442 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC17 | c.11233G>T p.V3745L | Missense Mutation (SNP) | VAF 25/281 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.444); called by muse, mutect2
- MUC19 | c.349-3A>G | Splice Region (SNP) | VAF 10/95 reads (11%) | called by muse, varscan2
- MYH1 | c.3038A>G p.D1013G | Missense Mutation (SNP) | VAF 43/694 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.12); called by muse, mutect2
- MYH4 | c.1919G>T p.G640V | Missense Mutation (SNP) | VAF 35/300 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- MYH6 | c.5386C>T p.Q1796* | Nonsense Mutation (SNP) | VAF 61/440 reads (14%) | called by muse, mutect2, varscan2
- MYL7 | c.392T>A p.L131H | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYO7B | c.3377G>T p.S1126I | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- NALCN | c.3553G>C p.A1185P | Missense Mutation (SNP) | VAF 33/370 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NAV2 | c.3851G>A p.S1284N (on ENST00000396087 / NM_001244963.2; = p.S1261N on NM_145117.5) | Missense Mutation (SNP) | VAF 18/406 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.045); called by muse, mutect2
- NCKAP5 | c.973C>A p.H325N | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.496); called by muse, mutect2
- NDUFA10 | c.805-1G>T p.X269_splice | Splice Site (SNP) | VAF 62/578 reads (11%) | called by mutect2, varscan2
- NEK9 | c.1182+7G>A | Splice Region (SNP) | VAF 23/266 reads (9%) | called by muse, mutect2
- NLGN4Y | c.104A>C p.K35T | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- NLRP5 | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- NOL4 | c.878G>C p.G293A | Missense Mutation (SNP) | VAF 52/460 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- NPY2R | c.27T>A p.D9E | Missense Mutation (SNP) | VAF 56/500 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ODR4 | c.343G>T p.V115L | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.086); called by muse, varscan2
- OOEP | c.225G>T p.W75C | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- OOEP | c.224G>T p.W75L | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- OR13C4 | c.491T>A p.M164K | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- OR51D1 | c.673C>G p.L225V | Missense Mutation (SNP) | VAF 46/732 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2
- OR52R1 | c.875C>A p.P292H | Missense Mutation (SNP) | VAF 46/223 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR8U1 | c.492C>A p.F164L | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.439); called by muse, varscan2
- OSBPL1A | c.2163G>C p.W721C (on ENST00000319481 / NM_080597.4; = p.W208C on NM_018030.4) | Missense Mutation (SNP) | VAF 14/323 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- OSBPL6 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.631); called by muse, mutect2
- OSBPL9 | c.269G>T p.W90L | Missense Mutation (SNP) | VAF 38/413 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- OTOF | c.4172C>G p.S1391C (on ENST00000272371 / NM_194248.3; = p.S624C on NM_004802.4) | Missense Mutation (SNP) | VAF 29/502 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.103); called by muse, mutect2
- OTOGL | c.1188T>A p.H396Q (on ENST00000547103; = p.H387Q on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OXCT1 | c.1431T>G p.D477E | Missense Mutation (SNP) | VAF 38/636 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- PBXIP1 | c.172G>T p.G58* | Nonsense Mutation (SNP) | VAF 25/219 reads (11%) | called by muse, mutect2, varscan2
- PCDH10 | c.1379_1380insA p.P461Afs*14 | Frame Shift Ins (INS) | VAF 33/253 reads (13%) | called by mutect2, pindel, varscan2
- PCDH11Y | c.3202C>G p.H1068D | Missense Mutation (SNP) | VAF 42/374 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHA8 | c.1477T>A p.S493T | Missense Mutation (SNP) | VAF 109/528 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PCDHB3 | c.1241G>C p.R414T | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PCDHGB4 | c.1082G>C p.G361A | Missense Mutation (SNP) | VAF 62/473 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCLO | c.11769G>T p.Q3923H | Missense Mutation (SNP) | VAF 87/476 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PGK2 | c.965A>T p.K322M | Missense Mutation (SNP) | VAF 44/449 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2
- PIK3C3 | c.976C>G p.Q326E | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PKD1 | c.2552C>G p.S851C | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, varscan2
- PKHD1 | c.11749C>T p.Q3917* | Nonsense Mutation (SNP) | VAF 40/642 reads (6%) | called by muse, mutect2
- PLBD1 | c.667T>A p.W223R | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.029); called by muse, mutect2
- PLCE1 | c.6856G>C p.E2286Q | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2
- PLCG2 | c.2666C>T p.A889V | Missense Mutation (SNP) | VAF 27/380 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PLK5 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.73); called by muse, mutect2
- PLXDC2 | c.677T>C p.V226A | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLXNB2 | c.4923G>C p.Q1641H | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- POGZ | c.2692G>C p.E898Q | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLQ | c.4484G>T p.S1495I | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- POM121L2 | c.2211C>A p.N737K | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.086); called by muse, mutect2
- POSTN | c.1790A>C p.E597A | Missense Mutation (SNP) | VAF 51/385 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POTEI | c.2320G>T p.G774C | Missense Mutation (SNP) | VAF 48/542 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POTEJ | c.1860G>T p.M620I | Missense Mutation (SNP) | VAF 54/714 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- PPP2R2B | c.296C>A p.P99H (on ENST00000394409; = p.P165H on NM_181674.2) | Missense Mutation (SNP) | VAF 40/247 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- PRAMEF4 | c.360A>C p.E120D | Missense Mutation (SNP) | VAF 49/508 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PRKAR1B | c.1124G>A p.S375N | Missense Mutation (SNP) | VAF 16/309 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); called by muse, mutect2
- PROK2 | c.362A>G p.N121S (on ENST00000295619 / NM_001126128.2; = p.N100S on NM_021935.4) | Missense Mutation (SNP) | VAF 24/526 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by muse, mutect2
- PRPF3 | c.1852G>C p.E618Q | Missense Mutation (SNP) | VAF 33/602 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.381); called by muse, mutect2
- PSKH2 | c.727G>T p.V243L | Missense Mutation (SNP) | VAF 91/475 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PTAR1 | c.553G>T p.G185C | Missense Mutation (SNP) | VAF 81/616 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPRQ | c.1471A>C p.T491P (on ENST00000616559; = p.T449P on NM_001145026.2) | Missense Mutation (SNP) | VAF 56/262 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.691); called by muse, varscan2
- PTPRQ | c.3421G>A p.V1141M (on ENST00000616559; = p.V1099M on NM_001145026.2) | Missense Mutation (SNP) | VAF 34/383 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- PUDP | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PYGO2 | c.1091G>T p.S364I | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PZP | c.584C>G p.S195* | Nonsense Mutation (SNP) | VAF 20/326 reads (6%) | called by muse, mutect2
- RAB40B | c.106G>C p.D36H | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- RABGGTA | c.1507G>T p.G503C | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RGPD4 | c.1727T>G p.L576R | Missense Mutation (SNP) | VAF 44/606 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.445); called by muse, mutect2
- RGS12 | c.2941G>T p.G981C | Missense Mutation (SNP) | VAF 45/269 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIN1 | c.1174G>C p.A392P | Missense Mutation (SNP) | VAF 45/379 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- RPA4 | c.318G>T p.Q106H | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RPGRIP1 | c.1393A>G p.I465V | Missense Mutation (SNP) | VAF 77/621 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPS6KB1 | c.1006C>G p.L336V | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); called by muse, mutect2
- RYR2 | c.12738T>A p.F4246L | Missense Mutation (SNP) | VAF 72/545 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- SALL1 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 33/287 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCG5 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 40/442 reads (9%) | called by muse, mutect2
- SCGN | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 22/340 reads (6%) | called by muse, mutect2
- SEC16A | c.4237A>T p.S1413C | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); called by muse, varscan2
- SEMA3E | c.678A>C p.K226N | Missense Mutation (SNP) | VAF 30/303 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- SEPTIN7 | c.1089G>A p.M363I | Missense Mutation (SNP) | VAF 33/355 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.426); called by muse, mutect2
- SH2D7 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.961); called by muse, mutect2
- SIN3B | c.1468G>T p.E490* | Nonsense Mutation (SNP) | VAF 16/95 reads (17%) | called by muse, mutect2, varscan2
- SLC12A5 | c.1955A>T p.Y652F (on ENST00000454036 / NM_001134771.2; = p.Y629F on NM_020708.5) | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- SLC14A1 | c.417G>C p.K139N | Missense Mutation (SNP) | VAF 69/578 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- SLC20A1 | c.1162T>C p.Y388H | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC22A2 | c.319C>A p.L107M | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SLC25A36 | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- SLC26A7 | c.217T>C p.S73P | Missense Mutation (SNP) | VAF 33/350 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2
- SLC2A5 | c.948C>A p.Y316* | Nonsense Mutation (SNP) | VAF 16/198 reads (8%) | called by muse, mutect2
- SLC39A9 | c.613A>T p.N205Y | Missense Mutation (SNP) | VAF 35/518 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.964); called by muse, mutect2
- SLC4A10 | c.1319C>A p.P440H (on ENST00000446997 / NM_001354461.2; = p.P410H on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC5A7 | c.1278T>A p.F426L | Missense Mutation (SNP) | VAF 51/354 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- SLCO1A2 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 17/244 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.114); called by muse, mutect2
- SLITRK1 | c.1079dup p.N360Kfs*10 | Frame Shift Ins (INS) | VAF 40/256 reads (16%) | called by mutect2, pindel, varscan2
- SLITRK5 | c.1648G>A p.D550N | Missense Mutation (SNP) | VAF 58/327 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SPANXB1 | c.253C>A p.P85T | Missense Mutation (SNP) | VAF 66/1542 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); called by muse, mutect2
- SPATA31A6 | c.3361C>A p.L1121I | Missense Mutation (SNP) | VAF 83/916 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- SPATA48 | c.26C>A p.P9H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, varscan2
- SPPL2C | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- SSC5D | c.3del p.M1? | Frame Shift Del (DEL) | VAF 32/280 reads (11%) | called by mutect2, pindel, varscan2
- SSTR1 | c.994C>A p.R332S | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- ST8SIA6 | c.340C>G p.P114A | Missense Mutation (SNP) | VAF 35/332 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- SUGP1 | c.1738G>T p.G580W | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYMPK | c.3541G>T p.G1181C | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- SYT6 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAFA2 | c.161A>T p.N54I | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAGAP | c.256T>C p.F86L | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TBC1D15 | c.985G>T p.E329* | Nonsense Mutation (SNP) | VAF 22/184 reads (12%) | called by muse, mutect2, varscan2
- TBP | c.888C>G p.I296M | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); called by muse, mutect2
- TBX4 | c.791+1G>T p.X264_splice | Splice Site (SNP) | VAF 18/182 reads (10%) | called by muse, mutect2
- TCP10L2 | c.986G>A p.C329Y | Missense Mutation (SNP) | VAF 46/292 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TEX15 | c.1577A>G p.N526S (on ENST00000256246; = p.N909S on NM_001350162.2) | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.91); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- THNSL1 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 21/257 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by muse, mutect2
- THRB | c.184A>G p.T62A | Missense Mutation (SNP) | VAF 83/495 reads (17%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- TJP1 | c.3083G>T p.G1028V | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2
- TMEM132E | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.602); called by muse, mutect2
- TMEM74 | c.635G>T p.R212L | Missense Mutation (SNP) | VAF 70/375 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNFAIP6 | c.261G>T p.M87I | Missense Mutation (SNP) | VAF 19/280 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.038); called by muse, mutect2
- TNS1 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.055); called by muse, mutect2
- TRANK1 | c.2384C>G p.T795S | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- TRIM3 | c.1941+1G>T p.X647_splice | Splice Site (SNP) | VAF 42/171 reads (25%) | called by muse, mutect2, varscan2
- TRIM51GP | c.1065T>A p.F355L | Missense Mutation (SNP) | VAF 79/494 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TRIP12 | c.305C>G p.S102* | Nonsense Mutation (SNP) | VAF 29/506 reads (6%) | called by muse, mutect2
- TTC39A | c.797C>G p.S266* (on ENST00000447632 / NM_001297665.1; = p.S231* on NM_001080494.3) | Nonsense Mutation (SNP) | VAF 14/212 reads (7%) | called by muse, mutect2
- TTLL6 | c.446C>A p.S149* | Nonsense Mutation (SNP) | VAF 22/400 reads (6%) | called by muse, mutect2
- UBQLN3 | c.1644C>A p.C548* | Nonsense Mutation (SNP) | VAF 43/387 reads (11%) | called by muse, mutect2, varscan2
- UGT2B4 | c.348G>T p.M116I | Missense Mutation (SNP) | VAF 37/316 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- USP34 | c.2815G>T p.D939Y | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2
- USP9X | c.2566G>C p.V856L | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- UTP25 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 52/469 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- VCPIP1 | c.1240G>T p.V414F | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- WASHC4 | c.2739G>T p.R913S | Missense Mutation (SNP) | VAF 58/362 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR45B | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 28/607 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); called by muse, mutect2
- WDR48 | c.1669-1G>A p.X557_splice | Splice Site (SNP) | VAF 16/242 reads (7%) | called by muse, mutect2
- WDR81 | c.2968C>T p.Q990* | Nonsense Mutation (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2, varscan2
- WWP2 | c.1594-1G>A p.X532_splice | Splice Site (SNP) | VAF 19/322 reads (6%) | called by muse, mutect2
- XIRP2 | c.8237C>A p.T2746K (on ENST00000628543; = p.T2921K on NM_152381.6) | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- XPO1 | c.791C>G p.S264C | Missense Mutation (SNP) | VAF 19/318 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2
- ZBBX | c.515C>G p.T172R | Missense Mutation (SNP) | VAF 88/374 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBED1 | c.147C>G p.I49M | Missense Mutation (SNP) | VAF 39/608 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- ZFC3H1 | c.1813C>G p.P605A | Missense Mutation (SNP) | VAF 52/671 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.656); called by muse, mutect2
- ZFHX3 | c.1340G>A p.G447D | Missense Mutation (SNP) | VAF 44/319 reads (14%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- ZFHX4 | c.757T>A p.S253T | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2
- ZFHX4 | c.8078A>G p.H2693R | Missense Mutation (SNP) | VAF 75/397 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZFP90 | c.1567A>T p.K523* | Nonsense Mutation (SNP) | VAF 31/210 reads (15%) | called by muse, mutect2, varscan2
- ZNF256 | c.682C>G p.Q228E | Missense Mutation (SNP) | VAF 34/307 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- ZNF267 | c.2063A>T p.Y688F | Missense Mutation (SNP) | VAF 65/458 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF423 | c.3055C>A p.P1019T (on ENST00000563137 / NM_001379286.1; = p.P1011T on NM_015069.4) | Missense Mutation (SNP) | VAF 45/313 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF468 | c.1358A>T p.H453L | Missense Mutation (SNP) | VAF 23/411 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.1); called by muse, mutect2
- ZNF492 | c.12C>A p.N4K | Missense Mutation (SNP) | VAF 46/494 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF518A | c.1606C>T p.Q536* | Nonsense Mutation (SNP) | VAF 21/127 reads (17%) | called by muse, mutect2, varscan2
- ZNF536 | c.1934A>T p.Q645L | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF644 | c.2283C>G p.F761L | Missense Mutation (SNP) | VAF 22/343 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF84 | c.1981G>T p.G661C | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZSCAN10 | c.34G>A p.E12K (on ENST00000252463; = p.E67K on NM_032805.3) | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ABCA10 | c.4056G>A p.L1352= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as COSV52220625; called by muse, mutect2
- ABCD3 | c.1863C>T p.F621= | Silent (SNP) | VAF 37/384 reads (10%) | called by muse, mutect2
- ADGRL2 | c.4002C>T p.S1334= (on ENST00000370717 / NM_001366005.1; = p.S1278= on NM_012302.4) | Silent (SNP) | VAF 18/142 reads (13%) | catalogued as rs756830878; called by muse, mutect2, varscan2
- ALS2CL | c.1582C>T p.L528= | Silent (SNP) | VAF 18/148 reads (12%) | called by muse, mutect2, varscan2
- AMER3 | c.672C>T p.A224= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs781424251, COSV58467950; called by mutect2, varscan2
- ANKRD24 | c.2895G>T p.S965= | Silent (SNP) | VAF 24/240 reads (10%) | catalogued as COSV99517284; called by muse, mutect2
- AP002512.3 | c.1080C>T p.F360= | Silent (SNP) | VAF 20/273 reads (7%) | catalogued as COSV54406807; called by muse, mutect2
- ARFGEF3 | c.2790T>C p.V930= | Silent (SNP) | VAF 25/129 reads (19%) | called by muse, mutect2, varscan2
- ARHGAP32 | c.3327C>T p.L1109= (on ENST00000310343 / NM_001378025.1; = p.L760= on NM_014715.4) | Silent (SNP) | VAF 33/381 reads (9%) | called by muse, mutect2
- ASPH | c.1494G>A p.L498= | Silent (SNP) | VAF 20/402 reads (5%) | called by muse, mutect2
- ASZ1 | c.1398C>T p.F466= | Silent (SNP) | VAF 16/141 reads (11%) | called by muse, mutect2, varscan2
- BRD9 | c.504A>C p.A168= | Silent (SNP) | VAF 87/555 reads (16%) | called by muse, mutect2, varscan2
- C11orf96 | c.1098C>T p.F366= (on ENST00000339446; = p.F53= on NM_001145033.2) | Silent (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- C7 | c.666C>G p.R222= | Silent (SNP) | VAF 18/352 reads (5%) | called by muse, mutect2
- CACNA1H | c.3864G>A p.Q1288= | Silent (SNP) | VAF 22/149 reads (15%) | called by muse, mutect2, varscan2
- CBX4 | c.54G>A p.K18= | Silent (SNP) | VAF 32/188 reads (17%) | called by muse, mutect2, varscan2
- CCSER1 | c.2241G>A p.V747= | Silent (SNP) | VAF 15/75 reads (20%) | called by muse, varscan2
- CENPI | c.1764C>T p.F588= | Silent (SNP) | VAF 16/181 reads (9%) | called by muse, varscan2
- CENPO | c.396G>A p.G132= | Silent (SNP) | VAF 24/310 reads (8%) | called by muse, mutect2
- CLEC4F | c.1473T>C p.H491= | Silent (SNP) | VAF 37/393 reads (9%) | called by muse, mutect2
- COL21A1 | c.780A>G p.T260= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs1277980392; called by muse, varscan2
- COL22A1 | c.1107G>C p.L369= | Silent (SNP) | VAF 40/378 reads (11%) | catalogued as rs762002714; called by muse, mutect2, varscan2
- COL3A1 | c.4338C>A p.P1446= | Silent (SNP) | VAF 30/309 reads (10%) | called by muse, mutect2, varscan2
- COL7A1 | c.24C>T p.A8= | Silent (SNP) | VAF 35/274 reads (13%) | catalogued as rs1205884066; called by muse, mutect2, varscan2
- DNAAF5 | c.951G>A p.Q317= | Silent (SNP) | VAF 21/273 reads (8%) | called by muse, mutect2
- DNAH17 | c.4032C>T p.I1344= | Silent (SNP) | VAF 27/489 reads (6%) | catalogued as COSV101103843; called by muse, mutect2
- DRD4 | c.522C>G p.L174= | Silent (SNP) | VAF 21/171 reads (12%) | called by muse, mutect2, varscan2
- DYRK3 | c.1203A>G p.E401= | Silent (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
- FAM186B | c.948C>T p.F316= | Silent (SNP) | VAF 18/123 reads (15%) | called by muse, mutect2, varscan2
- FAM186B | c.675C>T p.F225= | Silent (SNP) | VAF 16/92 reads (17%) | called by muse, varscan2
- FAT3 | c.12639C>T p.R4213= | Silent (SNP) | VAF 21/163 reads (13%) | catalogued as COSV53078901; called by muse, mutect2, varscan2
- FCGBP | c.1887G>T p.L629= | Silent (SNP) | VAF 34/335 reads (10%) | called by muse, mutect2, varscan2
- FREM1 | c.258C>A p.P86= | Silent (SNP) | VAF 41/249 reads (16%) | called by muse, mutect2, varscan2
- GABRG2 | c.1479C>T p.F493= (on ENST00000361925 / NM_001375343.1; = p.F453= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/418 reads (10%) | catalogued as COSV62724166; called by muse, mutect2
- GFRA4 | c.336C>A p.P112= | Silent (SNP) | VAF 18/246 reads (7%) | called by muse, mutect2
- GIMAP1-GIMAP5 | c.513C>A p.L171= | Silent (SNP) | VAF 94/458 reads (21%) | called by muse, mutect2, varscan2
- GKN2 | c.45G>C p.G15= | Silent (SNP) | VAF 30/461 reads (7%) | called by muse, mutect2
- GPRC5C | c.6G>T p.R2= | Silent (SNP) | VAF 22/219 reads (10%) | called by muse, varscan2
- H3C7 | c.99C>T p.T33= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs750825831; called by muse, mutect2, varscan2
- HHIPL2 | c.621C>T p.L207= | Silent (SNP) | VAF 13/145 reads (9%) | catalogued as rs1162171897, COSV58567241; called by muse, mutect2
- HMCN1 | c.13245T>C p.G4415= | Silent (SNP) | VAF 70/866 reads (8%) | called by muse, mutect2
- HRH2 | c.909C>T p.F303= | Silent (SNP) | VAF 23/294 reads (8%) | called by muse, mutect2
- HRH3 | c.447G>A p.T149= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs748667634; called by mutect2, varscan2
- IFNA8 | c.378A>G p.E126= | Silent (SNP) | VAF 52/442 reads (12%) | called by muse, mutect2, varscan2
- IGHV3-30 | c.204A>G p.A68= | Silent (SNP) | VAF 54/916 reads (6%) | catalogued as rs566240129; called by muse, mutect2
- IVNS1ABP | c.1257G>T p.V419= | Silent (SNP) | VAF 11/154 reads (7%) | catalogued as rs1229466846; called by muse, mutect2
- JPH1 | c.1542G>A p.L514= | Silent (SNP) | VAF 27/504 reads (5%) | catalogued as COSV60613945; called by muse, mutect2
- KDM5A | c.2928C>T p.S976= | Silent (SNP) | VAF 50/590 reads (8%) | catalogued as rs1191460711, COSV66991443; called by muse, mutect2
- KIF19 | c.852C>A p.I284= | Silent (SNP) | VAF 37/311 reads (12%) | catalogued as rs1282974968; called by muse, mutect2, varscan2
- KIF9 | c.447G>T p.L149= | Silent (SNP) | VAF 44/410 reads (11%) | called by muse, mutect2, varscan2
- KRT85 | c.225C>A p.S75= | Silent (SNP) | VAF 23/160 reads (14%) | catalogued as COSV57737374; called by muse, mutect2, varscan2
- KRTAP5-5 | c.183C>A p.G61= | Silent (SNP) | VAF 48/373 reads (13%) | catalogued as COSV101294185; called by muse, varscan2
- LAMB3 | c.1362G>C p.L454= | Silent (SNP) | VAF 18/291 reads (6%) | called by muse, mutect2
- LRP4 | c.2853G>T p.L951= | Silent (SNP) | VAF 20/342 reads (6%) | called by muse, mutect2
- LRRIQ1 | c.3258A>G p.L1086= | Silent (SNP) | VAF 52/265 reads (20%) | catalogued as rs767745281; called by muse, mutect2, varscan2
- LRRTM1 | c.1086G>T p.L362= | Silent (SNP) | VAF 22/96 reads (23%) | called by muse, mutect2, varscan2
- MAGEA4 | c.468C>T p.S156= | Silent (SNP) | VAF 25/129 reads (19%) | catalogued as rs202047929, COSV52341649; called by muse, mutect2, varscan2
- MAGEB6 | c.303C>G p.S101= | Silent (SNP) | VAF 63/207 reads (30%) | called by muse, mutect2, varscan2
- MICAL3 | c.654G>C p.V218= | Silent (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
- MTOR | c.5478C>T p.T1826= | Silent (SNP) | VAF 68/822 reads (8%) | catalogued as rs540000231; called by muse, mutect2
- MYH11 | c.2226C>T p.D742= | Silent (SNP) | VAF 84/702 reads (12%) | catalogued as rs745850224; called by muse, mutect2, varscan2
- MYH8 | c.1032C>T p.F344= | Silent (SNP) | VAF 71/618 reads (11%) | catalogued as rs369506465; called by muse, mutect2, varscan2
- MYO5B | c.3927G>T p.G1309= | Silent (SNP) | VAF 91/615 reads (15%) | called by muse, mutect2, varscan2
- NOBOX | c.174C>A p.I58= | Silent (SNP) | VAF 107/776 reads (14%) | called by muse, mutect2, varscan2
- NOVA1 | c.414C>A p.P138= | Silent (SNP) | VAF 22/240 reads (9%) | catalogued as COSV57486277; called by muse, mutect2
- OR10R2 | c.243C>T p.F81= | Silent (SNP) | VAF 26/306 reads (8%) | catalogued as rs1174996118, COSV100936795, COSV63769138; called by muse, mutect2
- OR11L1 | c.786C>T p.P262= | Silent (SNP) | VAF 21/184 reads (11%) | catalogued as COSV63314418; called by muse, mutect2, varscan2
- OR13C3 | c.945G>T p.G315= | Silent (SNP) | VAF 56/414 reads (14%) | catalogued as COSV66165973; called by muse, mutect2, varscan2
- OR2L2 | c.609C>A p.T203= | Silent (SNP) | VAF 42/392 reads (11%) | catalogued as COSV100823431; called by muse, mutect2, varscan2
- OR5L2 | c.432G>T p.L144= | Silent (SNP) | VAF 51/234 reads (22%) | catalogued as COSV101004303; called by muse, mutect2, varscan2
- OR8K1 | c.918T>A p.A306= | Silent (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2
- PIEZO2 | c.8169G>T p.L2723= | Silent (SNP) | VAF 92/509 reads (18%) | catalogued as COSV99555314; called by muse, mutect2, varscan2
- PKLR | c.786C>A p.P262= | Silent (SNP) | VAF 42/247 reads (17%) | catalogued as COSV61361537; called by muse, mutect2, varscan2
- PLPP3 | c.66C>A p.L22= | Silent (SNP) | VAF 16/179 reads (9%) | catalogued as COSV64839199; called by muse, mutect2
- PSKH2 | c.264T>A p.P88= | Silent (SNP) | VAF 94/372 reads (25%) | called by muse, mutect2, varscan2
- PTPRD | c.381C>A p.T127= | Silent (SNP) | VAF 29/259 reads (11%) | catalogued as COSV100645849; called by mutect2, varscan2
- PTPRZ1 | c.3447G>A p.E1149= | Silent (SNP) | VAF 33/157 reads (21%) | catalogued as rs766000430, COSV66433258; called by muse, mutect2, varscan2
- RELN | c.3501G>A p.L1167= | Silent (SNP) | VAF 88/518 reads (17%) | catalogued as rs778564879; called by muse, mutect2, varscan2
- RGPD4 | c.3738A>C p.T1246= | Silent (SNP) | VAF 128/860 reads (15%) | catalogued as COSV61747369; called by muse, mutect2, varscan2
- RHBDL3 | c.210G>T p.L70= | Silent (SNP) | VAF 39/312 reads (13%) | called by muse, mutect2, varscan2
- ROR2 | c.1998C>T p.Y666= | Silent (SNP) | VAF 35/440 reads (8%) | catalogued as rs773389306, COSV100996078, COSV65224658; called by muse, mutect2
- RYR2 | c.2850G>T p.V950= | Silent (SNP) | VAF 34/412 reads (8%) | catalogued as COSV63694548; called by muse, mutect2
- SDC4 | c.465C>T p.I155= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as rs1299598455; called by muse, mutect2
- SGO2 | c.1131A>T p.T377= | Silent (SNP) | VAF 9/116 reads (8%) | called by muse, mutect2
- SHOX | c.684G>T p.L228= | Silent (SNP) | VAF 53/282 reads (19%) | called by muse, mutect2, varscan2
- SIVA1 | c.57C>G p.R19= | Silent (SNP) | VAF 15/119 reads (13%) | called by muse, mutect2, varscan2
- SLC43A2 | c.1290C>T p.F430= | Silent (SNP) | VAF 22/322 reads (7%) | called by muse, mutect2
- SLC6A15 | c.165T>A p.S55= | Silent (SNP) | VAF 96/529 reads (18%) | called by muse, mutect2, varscan2
- SLFN13 | c.2397C>T p.F799= | Silent (SNP) | VAF 65/456 reads (14%) | called by muse, mutect2, varscan2
- SLITRK3 | c.1590C>A p.A530= | Silent (SNP) | VAF 51/232 reads (22%) | catalogued as COSV53845287, COSV53854126; called by muse, mutect2, varscan2
- SMAD9 | c.1155C>T p.F385= (on ENST00000379826 / NM_001127217.3; = p.F348= on NM_005905.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/461 reads (9%) | called by muse, mutect2
- SNAP25 | c.543C>A p.I181= | Silent (SNP) | VAF 39/185 reads (21%) | catalogued as COSV99655376; called by muse, mutect2, varscan2
- SNPH | c.180G>C p.L60= | Silent (SNP) | VAF 36/374 reads (10%) | catalogued as COSV67870776; called by muse, mutect2, varscan2
- SPHKAP | c.2745G>A p.T915= | Silent (SNP) | VAF 44/313 reads (14%) | catalogued as rs137996231; called by muse, mutect2, varscan2
- STYXL2 | c.87C>T p.Y29= | Silent (SNP) | VAF 22/274 reads (8%) | called by muse, mutect2
- TBC1D31 | c.2319A>G p.Q773= | Silent (SNP) | VAF 14/245 reads (6%) | called by muse, mutect2
- TEX13C | c.801A>T p.A267= | Silent (SNP) | VAF 31/186 reads (17%) | called by muse, mutect2, varscan2
- TGIF2LX | c.177C>G p.A59= | Silent (SNP) | VAF 29/274 reads (11%) | catalogued as COSV99383299, COSV99383406; called by muse, mutect2, varscan2
- TLR10 | c.168C>A p.S56= | Silent (SNP) | VAF 52/305 reads (17%) | called by muse, mutect2, varscan2
- TLR8 | c.2283C>T p.T761= (on ENST00000218032 / NM_138636.5; = p.T779= on NM_016610.4) | Silent (SNP) | VAF 18/166 reads (11%) | called by muse, mutect2, varscan2
- TMEM229B | c.402C>T p.F134= | Silent (SNP) | VAF 39/390 reads (10%) | called by muse, mutect2, varscan2
- TTN | c.9672G>A p.R3224= (on ENST00000591111; = p.R3178= on NM_003319.4) | Silent (SNP) | VAF 23/389 reads (6%) | catalogued as COSV100630501, COSV59906165; called by muse, mutect2
- TXK | c.435A>G p.L145= | Silent (SNP) | VAF 21/347 reads (6%) | called by muse, mutect2
- TYK2 | c.786A>G p.T262= | Silent (SNP) | VAF 32/207 reads (15%) | called by muse, mutect2, varscan2
- USH1C | c.921G>C p.A307= | Silent (SNP) | VAF 41/284 reads (14%) | called by muse, mutect2, varscan2
- VNN1 | c.903C>A p.L301= | Silent (SNP) | VAF 44/198 reads (22%) | called by muse, varscan2
- VPS13D | c.5505C>T p.I1835= | Silent (SNP) | VAF 29/275 reads (11%) | catalogued as rs761717515, COSV50640849; called by muse, mutect2, varscan2
- ZFP64 | c.168G>A p.L56= | Silent (SNP) | VAF 28/268 reads (10%) | called by muse, mutect2, varscan2
- ZNF521 | c.2485C>A p.R829= | Silent (SNP) | VAF 55/341 reads (16%) | catalogued as COSV64131138; called by muse, mutect2, varscan2
- ZNF521 | c.522C>T p.Y174= | Silent (SNP) | VAF 50/588 reads (9%) | catalogued as rs746171566; called by muse, mutect2
- ZNF534 | c.654A>G p.Q218= (on ENST00000332323 / NM_001143939.3; = p.Q205= on NM_001143938.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/355 reads (11%) | catalogued as rs753177019, COSV56517240, COSV99990144; called by muse, mutect2, varscan2
- ZNF550 | c.1179C>T p.H393= | Silent (SNP) | VAF 79/222 reads (36%) | catalogued as rs1369427565; called by muse, mutect2, varscan2
- AC136604.1 | n.105A>C | RNA (SNP) | VAF 19/225 reads (8%) | called by muse, varscan2
- ADARB2 | c.1683-62G>T | Intron (SNP) | VAF 26/164 reads (16%) | called by muse, varscan2
- ADORA2A | c.-274-1867C>G | Intron (SNP) | VAF 32/527 reads (6%) | catalogued as rs1033584242; called by muse, mutect2
- ADSS1 | c.193-5060C>A | Intron (SNP) | VAF 17/100 reads (17%) | called by muse, mutect2, varscan2
- AKAP17A | c.1152+155G>T | Intron (SNP) | VAF 4/26 reads (15%) | called by mutect2, varscan2
- AL353804.7 | chrX:73846427 G>T | 5'Flank (SNP) | VAF 40/244 reads (16%) | called by muse, mutect2, varscan2
- AMPH | c.1182+1311A>G | Intron (SNP) | VAF 26/226 reads (12%) | catalogued as COSV57749194; called by muse, mutect2, varscan2
- ANK2 | c.84+57143C>A | Intron (SNP) | VAF 16/142 reads (11%) | called by mutect2, varscan2
- AP001267.5 | c.-838G>T | 5'UTR (SNP) | VAF 20/173 reads (12%) | called by muse, mutect2, varscan2
- AP003062.1 | n.947C>A | RNA (SNP) | VAF 96/483 reads (20%) | called by muse, varscan2
- BACE2 | c.312+11037C>T | Intron (SNP) | VAF 64/772 reads (8%) | catalogued as rs778853538, COSV57737180; called by muse, mutect2
- C12orf57 | chr12:6943202 T>C | 5'Flank (SNP) | VAF 7/58 reads (12%) | called by muse, varscan2
- C5orf46 | c.-15C>T | 5'UTR (SNP) | VAF 33/167 reads (20%) | called by muse, mutect2, varscan2
- CA1 | c.235+33T>C | Intron (SNP) | VAF 24/291 reads (8%) | called by muse, mutect2
- CALCR | c.51+2959A>T | Intron (SNP) | VAF 23/341 reads (7%) | called by muse, mutect2
- CCDC40 | c.552+35C>T | Intron (SNP) | VAF 26/176 reads (15%) | catalogued as rs778485151; called by muse, mutect2, varscan2
- CCDC63 | c.-25G>T | 5'UTR (SNP) | VAF 68/419 reads (16%) | called by muse, varscan2
- CCDC63 | c.-24G>T | 5'UTR (SNP) | VAF 66/424 reads (16%) | called by muse, varscan2
- CLEC19A | c.*11C>T | 3'UTR (SNP) | VAF 34/476 reads (7%) | catalogued as rs1297387243; called by muse, mutect2
- CPLANE1 | c.*566G>T | 3'UTR (SNP) | VAF 113/567 reads (20%) | called by muse, mutect2, varscan2
- CPNE1 | c.-1+1675G>A | Intron (SNP) | VAF 47/409 reads (11%) | catalogued as rs778426459, COSV58290864; called by muse, mutect2
- CRISP3 | c.-13C>T | 5'UTR (SNP) | VAF 28/294 reads (10%) | called by muse, mutect2
- CYHR1 | c.246+55G>A | Intron (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2, varscan2
- DCD | c.98-428G>T | Intron (SNP) | VAF 51/224 reads (23%) | called by muse, mutect2, varscan2
- DCUN1D2 | c.3+220G>C | Intron (SNP) | VAF 6/30 reads (20%) | called by muse, varscan2
- DIRC1 | n.394A>G | RNA (SNP) | VAF 40/650 reads (6%) | catalogued as rs999616670, COSV57370427; called by muse, mutect2
- DOCK7 | c.*156G>T | 3'UTR (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2
- DRG1 | c.-1G>A | 5'UTR (SNP) | VAF 22/398 reads (6%) | catalogued as rs1456520595; called by muse, mutect2
- EGFLAM | c.-3G>T | 5'UTR (SNP) | VAF 18/302 reads (6%) | catalogued as COSV100473668; called by muse, mutect2
- EPB41L2 | c.2608-45T>A | Intron (SNP) | VAF 26/299 reads (9%) | called by muse, mutect2
- EPB41L3 | c.-11-25G>T | Intron (SNP) | VAF 24/205 reads (12%) | called by muse, mutect2, varscan2
- ETFB | c.58-122A>T | Intron (SNP) | VAF 28/260 reads (11%) | called by muse, varscan2
- FAM107A | c.-6C>T | 5'UTR (SNP) | VAF 36/198 reads (18%) | catalogued as rs1289485542; called by muse, mutect2, varscan2
- FAM215A | n.258C>T | RNA (SNP) | VAF 17/292 reads (6%) | called by muse, mutect2
- FGG | c.*484G>C | 3'UTR (SNP) | VAF 20/249 reads (8%) | called by muse, mutect2
- FRAS1 | c.108+2559G>A | Intron (SNP) | VAF 60/642 reads (9%) | called by muse, mutect2
- FRMD1 | c.870+163C>T | Intron (SNP) | VAF 12/106 reads (11%) | catalogued as rs781228836; called by mutect2, varscan2
- GABRG2 | c.1249-668G>C | Intron (SNP) | VAF 9/141 reads (6%) | called by muse, mutect2
- GCSH | c.149-472C>T | Intron (SNP) | VAF 18/218 reads (8%) | called by muse, mutect2
- GRM5 | c.661+62375G>T | Intron (SNP) | VAF 44/195 reads (23%) | catalogued as rs867049532; called by muse, mutect2, varscan2
- HMGA2 | c.249+13031G>A | Intron (SNP) | VAF 29/203 reads (14%) | catalogued as rs558894913; called by muse, mutect2, varscan2
- HOXA10 | c.*100G>T | 3'UTR (SNP) | VAF 35/221 reads (16%) | called by muse, mutect2, varscan2
- KIAA1958 | c.1172-27116C>T | Intron (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2, varscan2
- KLK13 | c.52+1337C>G | Intron (SNP) | VAF 18/334 reads (5%) | called by muse, mutect2
- LDB2 | c.236-78420G>T | Intron (SNP) | VAF 77/463 reads (17%) | called by muse, mutect2, varscan2
- LHX1 | chr17:36937168 C>A | 5'Flank (SNP) | VAF 22/196 reads (11%) | called by muse, mutect2, varscan2
- LMF1 | c.503+6859G>A | Intron (SNP) | VAF 47/328 reads (14%) | called by muse, mutect2, varscan2
- MAD2L2 | c.427+50C>T | Intron (SNP) | VAF 26/264 reads (10%) | catalogued as rs758780314, COSV52416815; called by muse, mutect2, varscan2
- MGAT4C | c.-30G>A | 5'UTR (SNP) | VAF 54/265 reads (20%) | called by muse, mutect2, varscan2
- MGAT4EP | n.1545G>T | RNA (SNP) | VAF 12/181 reads (7%) | called by muse, mutect2
- MICALL2 | c.641+28G>C | Intron (SNP) | VAF 24/423 reads (6%) | catalogued as rs1489228751; called by muse, mutect2
- MMP26 | c.-145+92885T>A | Intron (SNP) | VAF 33/291 reads (11%) | called by muse, mutect2, varscan2
- MOCS1 | c.*1249C>A | 3'UTR (SNP) | VAF 54/443 reads (12%) | called by muse, mutect2, varscan2
- MTSS1 | c.1036-893C>T | Intron (SNP) | VAF 22/133 reads (17%) | called by muse, mutect2, varscan2
- MYOM3 | c.3424-118G>T | Intron (SNP) | VAF 46/622 reads (7%) | catalogued as rs1485155521; called by muse, mutect2
- N4BP2 | c.230-2015G>T | Intron (SNP) | VAF 44/352 reads (13%) | called by muse, mutect2, varscan2
- NALCN | c.5023+13A>T | Intron (SNP) | VAF 71/517 reads (14%) | called by muse, mutect2, varscan2
- NFASC | c.-96G>T | 5'UTR (SNP) | VAF 20/274 reads (7%) | called by muse, mutect2
- NFASC | c.2471-1371G>T | Intron (SNP) | VAF 28/329 reads (9%) | called by muse, mutect2
- NFASC | c.2471-1370G>T | Intron (SNP) | VAF 26/326 reads (8%) | called by muse, mutect2
- OR52A4P | chr11:5120804 G>A | 3'Flank (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2
- P3H1 | c.941-21A>G | Intron (SNP) | VAF 52/518 reads (10%) | called by muse, mutect2, varscan2
- PDE4B | c.634+607G>T | Intron (SNP) | VAF 19/171 reads (11%) | called by muse, mutect2, varscan2
- PEX19 | c.*2249G>A | 3'UTR (SNP) | VAF 26/269 reads (10%) | called by muse, mutect2, varscan2
- PLA2G10 | c.356-5913G>C | Intron (SNP) | VAF 12/90 reads (13%) | catalogued as rs1056511847; called by muse, mutect2, varscan2
- PLEKHA5 | c.1846-5725C>T | Intron (SNP) | VAF 37/508 reads (7%) | called by muse, mutect2
- PPP2R1A | c.78+76T>A | Intron (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- PRSS1 | c.*24C>T | 3'UTR (SNP) | VAF 45/401 reads (11%) | catalogued as COSV100297761; called by muse, mutect2, varscan2
- PTGER3 | c.*24-12960C>A | Intron (SNP) | VAF 16/171 reads (9%) | called by muse, mutect2
- RALGDS | c.1758+30G>A | Intron (SNP) | VAF 25/191 reads (13%) | catalogued as rs1177402248; called by muse, mutect2, varscan2
- RETREG1 | c.-32G>T | 5'UTR (SNP) | VAF 24/81 reads (30%) | called by muse, mutect2, varscan2
- RFPL4AL1 | chr19:55777746 C>A | 3'Flank (SNP) | VAF 14/84 reads (17%) | called by muse, varscan2
- RPAIN | c.*26A>T | 3'UTR (SNP) | VAF 31/180 reads (17%) | catalogued as COSV99852204; called by muse, mutect2, varscan2
- SCD5 | c.232+44932C>A | Intron (SNP) | VAF 25/524 reads (5%) | called by muse, mutect2
- SH2D3C | c.516-5334C>A | Intron (SNP) | VAF 23/167 reads (14%) | called by muse, mutect2, varscan2
- SLC4A11 | chr20:3237933 C>T | 5'Flank (SNP) | VAF 22/150 reads (15%) | catalogued as rs962276732; called by muse, mutect2, varscan2
- SNU13 | chr22:41693611 A>C | 5'Flank (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- STAG3L4 | n.363-336C>T | Intron (SNP) | VAF 42/494 reads (9%) | called by muse, mutect2
- TAC4 | c.123+651_123+663del | Intron (DEL) | VAF 12/92 reads (13%) | called by mutect2, pindel
- TPI1 | c.*350C>A | 3'UTR (SNP) | VAF 16/99 reads (16%) | catalogued as rs11548736; called by muse, mutect2, varscan2
- TSBP1-AS1 | n.360C>T | RNA (SNP) | VAF 30/307 reads (10%) | called by muse, mutect2, varscan2
- TUBB7P | n.540G>T | RNA (SNP) | VAF 59/471 reads (13%) | called by muse, varscan2
- WLS | c.106+373C>G | Intron (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2
- XKR4 | c.806+60867C>T | Intron (SNP) | VAF 45/162 reads (28%) | called by muse, mutect2, varscan2
- ZEB2 | c.331+9C>A | Intron (SNP) | VAF 15/228 reads (7%) | called by muse, mutect2
- ZIC4 | c.-16+929G>C | Intron (SNP) | VAF 78/302 reads (26%) | called by muse, mutect2, varscan2
